Somatic mutation profile of tumor specimen HCM-BROD-0100-C15-01A (aliquot HCM-BROD-0100-C15-01A-11D-A786-36) from HCMI case HCM-BROD-0100-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.4 years (23,514 days).
Specimen HCM-BROD-0100-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7de9a3b1-98ea-4ad3-96c2-39846f33338f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0100-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0100-C15-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f45af831-fac8-4b4a-92bf-2412ca6d6b2f

The open-access MAF lists 135 somatic variants for this specimen: 84 protein-altering or splice-affecting, 30 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 30, Nonsense Mutation 7, 5'UTR 6, Intron 5, 3'UTR 4, Frame Shift Ins 3, 3'Flank 3, RNA 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs373890183; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.658T>A p.Y220N | Missense Mutation (SNP) | VAF 165/358 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs768366466, COSV55869035; called by muse, mutect2, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 376/1456 reads (26%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3046C>G p.Q1016E | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV51845014; called by muse, mutect2, varscan2
- ANKRD9 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751023237, COSV54601208; called by muse, mutect2, varscan2
- APOBEC1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99981037; called by muse, mutect2, varscan2
- ARMC5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as rs763409959, COSV51655724; called by muse, mutect2, varscan2
- ASB18 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs571890106; called by muse, mutect2, varscan2
- ATF2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99908360; called by muse, mutect2, varscan2
- BRSK2 | c.872C>A p.S291* | Nonsense Mutation (SNP) | VAF 57/334 reads (17%) | catalogued as COSV57545394; called by muse, mutect2, varscan2
- C3 | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV55582481; called by muse, mutect2, varscan2
- CACNB2 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 131/463 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as rs750972281; called by muse, mutect2, varscan2
- CSMD1 | c.9496C>T p.R3166* (on ENST00000520002; = p.R3165* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as COSV59293387, COSV59386731; called by muse, mutect2, varscan2
- CSMD3 | c.3976C>A p.Q1326K (on ENST00000297405 / NM_001363185.1; = p.Q1222K on NM_052900.3) | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs1307365584, COSV52104687; called by muse, mutect2
- CSPP1 | c.1222C>T p.P408S (on ENST00000676605; = p.P367S on NM_024790.6) | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs1472100427; called by muse, mutect2
- CYP4F8 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1190402029, COSV100358121, COSV100358167; called by muse, mutect2, varscan2
- G3BP2 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.607); catalogued as rs1439916523, COSV62975976; called by muse, mutect2, varscan2
- GABRP | c.1019G>T p.R340M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs74690886; called by mutect2, varscan2
- GOLGA6L2 | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs1263624450; called by muse, mutect2, varscan2
- GP9 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 224/815 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs772819137, COSV56623758; called by muse, mutect2, varscan2
- ICE1 | c.1648A>C p.T550P | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56818771, COSV56834087; called by muse, mutect2, varscan2
- JRKL | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs750771684; called by muse, mutect2, varscan2
- MME | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 51/412 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as rs1242791354, COSV64706698; called by muse, mutect2, varscan2
- MUC5B | c.7435G>A p.G2479R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs760745894; called by mutect2, varscan2
- OR2G2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs372540193, COSV100189977; called by muse, mutect2
- PCDHGA12 | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV52774003; called by muse, mutect2, varscan2
- PEG10 | c.490C>T p.R164* (on ENST00000482108 / NM_001040152.2; = p.R198* on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 157/311 reads (50%) | catalogued as COSV101509909; called by muse, mutect2, varscan2
- POLDIP2 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1555580367; called by muse, mutect2, varscan2
- SLC25A6 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 118/652 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1475285619; called by muse, mutect2, varscan2
- TEX15 | c.6060dup p.Y2021Ifs*8 (on ENST00000256246; = p.Y2404Ifs*8 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 20/134 reads (15%) | catalogued as rs770974731; called by mutect2, varscan2
- TFAP2C | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 188/774 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as rs369684214; called by muse, mutect2, varscan2
- TTC6 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.017); catalogued as COSV73284676; called by muse, mutect2, varscan2
- ZNF407 | c.5578C>T p.P1860S | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1479177815; called by muse, mutect2, varscan2
- ZNF619 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs377170323; called by muse, mutect2, varscan2
- ABCC9 | c.2657A>T p.K886I | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADAMTS19 | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRD2 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ALOX12B | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARAP3 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- CAMK4 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CHD7 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 105/251 reads (42%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CORO7 | c.2515C>G p.L839V | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTCFL | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 156/428 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DCC | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCC | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EBF3 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ELP1 | c.2737-1G>A p.X913_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | called by mutect2, varscan2
- EP300 | c.3972_3976dup p.V1326Efs*2 | Frame Shift Ins (INS) | VAF 69/405 reads (17%) | called by mutect2, varscan2
- FANCD2 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- FANCM | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FAT4 | c.14582A>C p.K4861T | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- FOXB2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.824A>C p.N275T | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- GLRX3 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- HES2 | c.332T>G p.V111G | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- IARS2 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- INKA1 | c.255del p.R86Gfs*55 | Frame Shift Del (DEL) | VAF 39/250 reads (16%) | called by mutect2, pindel, varscan2
- IQCN | c.2561C>A p.A854D | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- LILRA1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LPO | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- MYRIP | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEB | c.9916T>C p.S3306P | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NLRP14 | c.3082T>C p.Y1028H | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOS3 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.217); called by muse, mutect2
- OR5M1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAFAH2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PEG3 | c.4148T>A p.V1383E | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF14 | c.2286G>A p.M762I | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PLXNA3 | c.4306C>T p.L1436F | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP2R1A | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RMC1 | c.1925dup p.K643Qfs*35 | Frame Shift Ins (INS) | VAF 18/157 reads (11%) | called by mutect2, varscan2
- SCUBE2 | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A14 | c.34A>T p.R12* | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | called by mutect2, varscan2
- SORCS3 | c.2306C>G p.A769G | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- STAC | c.244A>C p.S82R | Missense Mutation (SNP) | VAF 56/760 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, mutect2
- STARD9 | c.6750A>T p.K2250N | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYNE1 | c.21076G>C p.E7026Q (on ENST00000367255 / NM_182961.4; = p.E6955Q on NM_033071.3) | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM64 | c.818A>C p.N273T | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TRAPPC8 | c.1310A>T p.D437V | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- UNC79 | c.3692T>C p.V1231A (on ENST00000393151 / NM_001346218.2; = p.V1054A on NM_020818.5) | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF582 | c.150del p.K51Nfs*4 | Frame Shift Del (DEL) | VAF 28/203 reads (14%) | called by mutect2, pindel, varscan2
- ZNF714 | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY7 | c.1878G>T p.G626= | Silent (SNP) | VAF 48/458 reads (10%) | called by muse, mutect2, varscan2
- ALG8 | c.855C>T p.F285= | Silent (SNP) | VAF 156/421 reads (37%) | catalogued as rs1284684052; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6387A>G p.P2129= | Silent (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- BEND3 | c.391C>T p.L131= | Silent (SNP) | VAF 149/280 reads (53%) | catalogued as rs1554231931; called by muse, mutect2, varscan2
- COL27A1 | c.1533T>C p.T511= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV100621048; called by muse, mutect2, varscan2
- DDC | c.1416C>T p.A472= | Silent (SNP) | VAF 80/676 reads (12%) | catalogued as rs892676540; called by muse, mutect2, varscan2
- DGKG | c.702C>T p.Y234= | Silent (SNP) | VAF 39/340 reads (11%) | catalogued as rs202148280; called by muse, mutect2, varscan2
- DLC1 | c.3333G>A p.G1111= (on ENST00000276297 / NM_001348081.2; = p.G674= on NM_006094.5) | Silent (SNP) | VAF 45/269 reads (17%) | catalogued as rs1229196167; called by muse, mutect2, varscan2
- EIF4A2 | c.258A>C p.T86= | Silent (SNP) | VAF 109/418 reads (26%) | called by muse, mutect2, varscan2
- FMO2 | c.423C>T p.D141= | Silent (SNP) | VAF 46/288 reads (16%) | catalogued as rs144325714; called by muse, mutect2, varscan2
- IQSEC2 | c.261C>T p.S87= | Silent (SNP) | VAF 64/170 reads (38%) | called by muse, mutect2, varscan2
- MROH5 | c.3450G>A p.A1150= | Silent (SNP) | VAF 28/346 reads (8%) | catalogued as rs375142667; called by muse, mutect2
- NETO2 | c.1161C>T p.T387= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as rs771545207, COSV57454566; called by muse, mutect2, varscan2
- OR6B3 | c.282C>T p.F94= | Silent (SNP) | VAF 14/278 reads (5%) | catalogued as rs751578693, COSV60113642; called by muse, mutect2
- ORM1 | c.138C>T p.I46= | Silent (SNP) | VAF 144/1504 reads (10%) | catalogued as rs370324189; called by muse, mutect2
- PARD6G | c.915C>T p.G305= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as rs369128345; called by muse, mutect2, varscan2
- PCDH8 | c.2373G>T p.R791= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1276T>C p.L426= | Silent (SNP) | VAF 134/378 reads (35%) | catalogued as rs782595480, COSV100697139; called by muse, mutect2, varscan2
- PCDHGB2 | c.1647C>T p.R549= | Silent (SNP) | VAF 213/654 reads (33%) | catalogued as COSV53935346; called by muse, mutect2, varscan2
- PDCD2 | c.396T>A p.A132= | Silent (SNP) | VAF 78/520 reads (15%) | called by muse, mutect2, varscan2
- PPP1R26 | c.3319C>T p.L1107= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2, varscan2
- RNF114 | c.327T>G p.T109= | Silent (SNP) | VAF 45/262 reads (17%) | called by muse, mutect2, varscan2
- SHANK1 | c.2352G>T p.L784= | Silent (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- SLC25A51 | c.870T>C p.Y290= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as rs1201539831; called by muse, varscan2
- SLC6A13 | c.622C>T p.L208= | Silent (SNP) | VAF 31/426 reads (7%) | catalogued as rs746681927, COSV58257434; called by muse, mutect2
- SORCS1 | c.273G>T p.R91= | Silent (SNP) | VAF 92/207 reads (44%) | catalogued as COSV99545513; called by muse, mutect2, varscan2
- STAC | c.243C>A p.P81= | Silent (SNP) | VAF 56/760 reads (7%) | called by muse, mutect2
- TJAP1 | c.753C>T p.S251= (on ENST00000372445 / NM_001146016.1; = p.S241= on NM_080604.3) | Silent (SNP) | VAF 428/855 reads (50%) | catalogued as rs762556744; called by muse, mutect2, varscan2
- WDR59 | c.246C>T p.N82= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs1045744438; called by muse, mutect2, varscan2
- ZNF318 | c.231C>A p.R77= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, varscan2
- ADD2 | c.-7C>T | 5'UTR (SNP) | VAF 19/89 reads (21%) | catalogued as rs372674293, COSV100034788; called by muse, mutect2
- AKR1B1P6 | n.84G>C | RNA (SNP) | VAF 39/219 reads (18%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827808 G>A | 3'Flank (SNP) | VAF 31/457 reads (7%) | called by muse, mutect2
- ARFGAP1 | c.*578G>A | 3'UTR (SNP) | VAF 188/750 reads (25%) | catalogued as rs552679156; called by muse, mutect2, varscan2
- CENPW | c.126+36C>A | Intron (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- CFL2 | c.*1590G>T | 3'UTR (SNP) | VAF 81/438 reads (18%) | called by muse, mutect2, varscan2
- COL4A3 | c.-8C>T | 5'UTR (SNP) | VAF 270/615 reads (44%) | called by muse, mutect2, varscan2
- DEK | c.*453G>A | 3'UTR (SNP) | VAF 24/71 reads (34%) | catalogued as rs372245813; called by muse, mutect2, varscan2
- DSCR4 | n.445G>A | RNA (SNP) | VAF 29/212 reads (14%) | catalogued as rs182817600; called by muse, mutect2, varscan2
- DTX3 | c.-57A>T | 5'UTR (SNP) | VAF 72/158 reads (46%) | called by muse, mutect2, varscan2
- EYS | c.749-827A>T | Intron (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- FEZ2 | c.904-2352C>G | Intron (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- FOLH1B | n.959A>G | RNA (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- GPR107 | chr9:130141641 C>T | 3'Flank (SNP) | VAF 41/284 reads (14%) | catalogued as rs554003487; called by muse, mutect2, varscan2
- PTPRT | c.2983-729G>A | Intron (SNP) | VAF 50/206 reads (24%) | catalogued as rs778174167, COSV61974000; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22607809 T>G | 3'Flank (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2, varscan2
- SCAPER | c.-82C>G | 5'UTR (SNP) | VAF 9/55 reads (16%) | catalogued as rs887905627; called by muse, mutect2, varscan2
- SGCZ | c.40-298538G>T | Intron (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- SKIV2L | c.-16C>T | 5'UTR (SNP) | VAF 30/130 reads (23%) | catalogued as rs1342660765; called by muse, mutect2, varscan2
- SLC6A5 | c.*5G>C | 3'UTR (SNP) | VAF 72/436 reads (17%) | catalogued as rs1210118623, COSV100117184; called by muse, mutect2, varscan2
- TRIM48 | c.-74T>G | 5'UTR (SNP) | VAF 82/205 reads (40%) | called by muse, mutect2, varscan2
